CPTAC case C3L-02513 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/283e6ba3-2654-4cbb-b57f-c0a63f4c2bbf

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1944; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 74.0 years (27,012 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Tumor grade: G1; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,666 days (4.6 years); Progression or recurrence: no; Days to last follow up: 1,666 days (4.6 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.4 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 21; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 510 days (1.4 years); Disease response: Tumor Free.
- Days to follow up: 601 days (1.6 years); Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 726 days (2.0 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 966 days (2.6 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,336 days (3.7 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,666 days (4.6 years); Disease response: Tumor Free; ECOG performance status: 0.

Other clinical attributes
- Weight: 102 kg; Height: 188 cm; BMI: 28.86; Diabetes treatment type: Insulin.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 34; Cigarettes per day: 20; Tobacco smoking onset year: 1961; Tobacco smoking quit year: 1995; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 34.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02513-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 146 mg; Time between excision and freezing: 37 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02513-23: Section location: Right Lower Lobe; Percent tumor nuclei: 80; Percent necrosis: 3.
- Sample C3L-02513-04: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -11 days; Initial weight: 152 mg; Time between excision and freezing: 39 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02513-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -11 days; Method of sample procurement: Blood Draw.
